Gene-level copy-number profile of tumor specimen C3N-04283-03 from CPTAC case C3N-04283, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 66.2 years (24,187 days).
Specimen C3N-04283-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c67e778d-c4e3-49a3-b0da-24c22f4499be.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04283-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/ce09b77e-c2f9-4a49-aac8-56b5167581fa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 112; copy number 1: 15,313; copy number 2: 42,265; copy number 3: 626; copy number 4: 87; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 112 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:120,710,698–120,790,778, 2 genes: RNU4-69P, AC114284.1.
- chr6:8,102,711–9,294,133, 7 genes: AL355499.1, AL355499.2, AL359378.1, SLC35B3, HULC, AL161437.1, AL137220.1.
- chr9:19,705,338–22,455,740, 72 genes (within-gene range 0–2) (broad region; genes not listed).
- chr18:50,302,190–53,581,107, 31 genes (within-gene range 0–1): AC105227.1, AC105227.2, RNA5SP458, SKA1, RPLP0P11, MAPK4, AC012433.2, AC012433.1, MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.1, DCC, AC011155.1, VN1R76P, MIR4528, LINC01917.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,642,383–61,642,494, 1 gene, copy number 6: Y_RNA.

Autosomal genes at a single copy (total copy number 1): 12,969. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
